Somatic mutation profile of cancer-model specimen HCM-SANG-0269-C18-85A (3D Organoid; aliquot HCM-SANG-0269-C18-85A-01D-A79M-36), derived from the primary tumor of HCMI case HCM-SANG-0269-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G2.
Specimen HCM-SANG-0269-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 019c6574-2677-4b70-8a86-3d014afaac01.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0269-C18-10A (Blood Derived Normal), aliquot HCM-SANG-0269-C18-10A-01D-A79M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3012dafa-1af3-4de5-bfc9-0e2dcc150444

The open-access MAF lists 165 somatic variants for this specimen: 113 protein-altering or splice-affecting, 49 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 99, Silent 49, Nonsense Mutation 7, In Frame Del 3, Frame Shift Del 2, Frame Shift Ins 2, 5'Flank 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 135/297 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.470T>G p.V157G | Missense Mutation (SNP) | VAF 148/148 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM138009, CM161671, COSV52675572, COSV52699845, COSV52722122; called by muse, mutect2, varscan2
- AARD | c.313C>T p.R105W | Missense Mutation (SNP) | VAF 414/564 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1293165731; called by muse, mutect2, varscan2
- APC | c.3827del p.S1276Yfs*12 | Frame Shift Del (DEL) | VAF 70/213 reads (33%) | catalogued as CD086479, CM086472, CM990161, COSV57326440, COSV57333387, COSV57352939; called by mutect2, pindel, varscan2
- APC | c.4384A>T p.K1462* | Nonsense Mutation (SNP) | VAF 180/309 reads (58%) | catalogued as CD084032, COSV99967451; called by muse, mutect2, varscan2
- APOB | c.5419G>T p.D1807Y | Missense Mutation (SNP) | VAF 203/411 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV51925891; called by muse, mutect2, varscan2
- ARHGAP22 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 246/594 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.541); catalogued as rs1011636325; called by muse, mutect2, varscan2
- ATP10A | c.2261G>A p.R754Q | Missense Mutation (SNP) | VAF 230/349 reads (66%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as rs1567323628, COSV63513572, COSV63516320; called by muse, mutect2, varscan2
- BAIAP2 | c.1597G>A p.A533T | Missense Mutation (SNP) | VAF 214/342 reads (63%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs764303213, COSV58373796; called by muse, varscan2
- CA12 | c.347C>T p.T116M | Missense Mutation (SNP) | VAF 129/507 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.737); catalogued as rs770085807, COSV51605502; called by muse, mutect2, varscan2
- CALHM2 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 183/258 reads (71%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as rs764724185; called by muse, mutect2, varscan2
- CCDC181 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 210/316 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376964448; called by muse, mutect2, varscan2
- CDH23 | c.8443C>T p.R2815C | Missense Mutation (SNP) | VAF 175/683 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as rs768583951, COSV56474975; called by muse, mutect2, varscan2
- CFAP45 | c.1321C>T p.R441W | Missense Mutation (SNP) | VAF 129/377 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1202413837, COSV63648382; called by muse, mutect2, varscan2
- CGB2 | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 49/509 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.079); catalogued as rs576183783; called by muse, mutect2, varscan2
- CHD8 | c.5217G>A p.W1739* (on ENST00000646647 / NM_001170629.2; = p.W1460* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 216/377 reads (57%) | catalogued as rs1555313639; called by muse, mutect2, varscan2
- CHRNB3 | c.765C>G p.F255L | Missense Mutation (SNP) | VAF 193/710 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99251259; called by muse, mutect2, varscan2
- CTSC | c.743C>A p.P248H | Missense Mutation (SNP) | VAF 60/196 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57059758; called by muse, mutect2, varscan2
- DCLK1 | c.217G>A p.V73M | Missense Mutation (SNP) | VAF 251/477 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.679); catalogued as COSV99708700; called by muse, mutect2, varscan2
- DDI1 | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 258/402 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs951750418, COSV56376481; called by muse, mutect2, varscan2
- DDX58 | c.2254C>A p.Q752K | Missense Mutation (SNP) | VAF 204/566 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs570533013; called by muse, mutect2
- DISP3 | c.3827C>T p.T1276M | Missense Mutation (SNP) | VAF 127/248 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs769502435, COSV53839869; called by muse, mutect2, varscan2
- DNAH5 | c.10264G>T p.E3422* | Nonsense Mutation (SNP) | VAF 80/267 reads (30%) | catalogued as COSV99453482; called by muse, mutect2, varscan2
- DYNC1I1 | c.1049G>A p.R350H | Missense Mutation (SNP) | VAF 88/260 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs376275541, COSV61461083; called by muse, varscan2
- EHMT1 | c.860G>A p.R287Q | Missense Mutation (SNP) | VAF 152/277 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs759057973; called by muse, mutect2, varscan2
- ERICH3 | c.493C>G p.R165G | Missense Mutation (SNP) | VAF 97/194 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); catalogued as COSV58603805, COSV58604538; called by muse, mutect2, varscan2
- FBXL7 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 301/464 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs1330246214, COSV61644173; called by muse, mutect2, varscan2
- FREM3 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 158/324 reads (49%) | SIFT tolerated (0.47); PolyPhen benign (0.021); catalogued as rs954380930; called by muse, mutect2, varscan2
- GPAT4 | c.740A>G p.N247S | Missense Mutation (SNP) | VAF 575/683 reads (84%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV67841872; called by muse, mutect2, varscan2
- GPR149 | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 102/471 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs527609541; called by muse, mutect2, varscan2
- GRIK3 | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 117/253 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1385414725; called by muse, mutect2, varscan2
- GRM6 | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 118/238 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV51447712; called by muse, mutect2, varscan2
- HYDIN | c.12553G>A p.E4185K | Missense Mutation (SNP) | VAF 143/252 reads (57%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.469); catalogued as rs750919238, COSV66638327; called by muse, mutect2, varscan2
- INTU | c.2255G>C p.S752T | Missense Mutation (SNP) | VAF 52/111 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs764304392; called by muse, mutect2, varscan2
- INVS | c.1790G>A p.R597Q | Missense Mutation (SNP) | VAF 133/254 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.773); catalogued as rs1291135236; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- JAG2 | c.2435G>A p.R812H | Missense Mutation (SNP) | VAF 84/426 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775717962, COSV59309588; called by muse, mutect2, varscan2
- MKRN2OS | c.148A>G p.N50D | Missense Mutation (SNP) | VAF 150/386 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as rs1180580585; called by muse, mutect2, varscan2
- MUC2 | c.2279C>T p.T760M | Missense Mutation (SNP) | VAF 125/400 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs766355002; called by muse, mutect2, varscan2
- MYCT1 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 307/469 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs17852097, COSV65891766; called by muse, mutect2
- NDC80 | c.1420A>G p.K474E | Missense Mutation (SNP) | VAF 80/80 reads (100%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as rs1201841950; called by muse, mutect2, varscan2
- NFX1 | c.1158A>G p.I386M | Missense Mutation (SNP) | VAF 237/586 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs754893922; called by muse, mutect2, varscan2
- NR1H2 | c.1220G>A p.R407H | Missense Mutation (SNP) | VAF 112/386 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.694); catalogued as rs1294071211, COSV53799747; called by muse, mutect2, varscan2
- NUDT7 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 80/265 reads (30%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.657); catalogued as rs541244539, COSV99216088; called by muse, mutect2, varscan2
- OR6P1 | c.59C>T p.T20M | Missense Mutation (SNP) | VAF 94/304 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.092); catalogued as rs776951618, COSV58109037; called by muse, mutect2, varscan2
- OR7A5 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 274/434 reads (63%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.187); catalogued as rs112260964; called by muse, mutect2, varscan2
- PCDHGC4 | c.1052C>A p.T351K | Missense Mutation (SNP) | VAF 23/386 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.84); catalogued as COSV52759422; called by muse, mutect2
- PCDHGC5 | c.2350G>A p.G784S | Missense Mutation (SNP) | VAF 185/450 reads (41%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs376104513; called by muse, mutect2, varscan2
- PDE1B | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 58/155 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs373781937; called by muse, mutect2, varscan2
- PDZD2 | c.1610G>A p.R537Q | Missense Mutation (SNP) | VAF 134/451 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs746903747, COSV56852185; called by muse, mutect2, varscan2
- PEG3 | c.4207G>A p.E1403K | Missense Mutation (SNP) | VAF 359/562 reads (64%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.904); catalogued as rs568262074, COSV99686616; called by muse, mutect2, varscan2
- PIWIL1 | c.1436C>G p.S479C | Missense Mutation (SNP) | VAF 25/423 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1417096071, COSV55349041; called by muse, mutect2
- REC8 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 111/449 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV61015458; called by muse, mutect2, varscan2
- ROBO1 | c.1126G>A p.G376R | Missense Mutation (SNP) | VAF 86/208 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766936398, COSV101458472, COSV71398526; called by muse, mutect2, varscan2
- SCN10A | c.4727G>A p.R1576H | Missense Mutation (SNP) | VAF 100/284 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs777606824, COSV71860179; called by muse, mutect2, varscan2
- SH2D4B | c.884G>A p.R295H (on ENST00000646907; = p.R294H on NM_207372.2) | Missense Mutation (SNP) | VAF 78/282 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.597); catalogued as rs773391724, COSV100214313, COSV57900459; called by muse, mutect2, varscan2
- SHISA2 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 246/482 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs201279413; called by muse, mutect2, varscan2
- SHISAL2B | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 220/360 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs374375151; called by muse, mutect2, varscan2
- SHROOM1 | c.1966G>A p.A656T | Missense Mutation (SNP) | VAF 140/386 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.06); catalogued as rs748264255, COSV60581765; called by muse, mutect2
- SREBF2 | c.3355C>T p.R1119W | Missense Mutation (SNP) | VAF 342/342 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs756039618; called by muse, mutect2, varscan2
- SYS1 | c.466G>T p.V156F | Missense Mutation (SNP) | VAF 12/436 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV54781528; called by muse, mutect2
- TAF11L13 | c.500C>T p.T167M | Missense Mutation (SNP) | VAF 153/254 reads (60%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs568945747; called by muse, mutect2, varscan2
- TBX5 | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 375/718 reads (52%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as rs1214991478; called by muse, mutect2, varscan2
- THSD7A | c.4378C>A p.P1460T | Missense Mutation (SNP) | VAF 175/267 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs892473253; called by muse, mutect2, varscan2
- TMEM132C | c.1919C>T p.T640M | Missense Mutation (SNP) | VAF 126/248 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1304548134; called by muse, mutect2, varscan2
- TTLL10 | c.248G>A p.R83Q (on ENST00000379289 / NM_001130045.2; = p.R10Q on NM_153254.3) | Missense Mutation (SNP) | VAF 189/370 reads (51%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.011); catalogued as rs772262149; called by muse, mutect2, varscan2
- USP2 | c.704C>T p.T235M | Missense Mutation (SNP) | VAF 287/467 reads (61%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs369895568; called by muse, mutect2, varscan2
- ZNF562 | c.33dup p.P12Sfs*9 | Frame Shift Ins (INS) | VAF 103/197 reads (52%) | catalogued as rs1045736988; called by mutect2, pindel, varscan2
- ZNF578 | c.1034G>T p.C345F | Missense Mutation (SNP) | VAF 32/296 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1331076393; called by muse, mutect2, varscan2
- ACAD10 | c.1957G>A p.V653I | Missense Mutation (SNP) | VAF 280/549 reads (51%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACBD3 | c.898C>T p.Q300* | Nonsense Mutation (SNP) | VAF 59/209 reads (28%) | called by muse, mutect2, varscan2
- ADAMTSL2 | c.458C>T p.T153I | Missense Mutation (SNP) | VAF 319/593 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- ADSS2 | c.385A>T p.I129L | Missense Mutation (SNP) | VAF 54/178 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- AMER1 | c.1712G>A p.W571* | Nonsense Mutation (SNP) | VAF 517/517 reads (100%) | called by muse, mutect2, varscan2
- BCORL1 | c.2906A>G p.Q969R | Missense Mutation (SNP) | VAF 145/508 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- C1QL3 | c.184C>G p.P62A | Missense Mutation (SNP) | VAF 168/660 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- C2orf16 | c.1426A>T p.N476Y | Missense Mutation (SNP) | VAF 236/444 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- CAMTA1 | c.2360G>A p.S787N | Missense Mutation (SNP) | VAF 151/329 reads (46%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- DNAH12 | c.2409A>T p.K803N (on ENST00000351747; = p.K826N on NM_001366028.2) | Missense Mutation (SNP) | VAF 162/299 reads (54%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- E2F8 | c.1173_1177del p.F391Lfs*15 | Frame Shift Del (DEL) | VAF 176/286 reads (62%) | called by pindel, varscan2
- FAIM | c.382G>T p.E128* | Nonsense Mutation (SNP) | VAF 107/252 reads (42%) | called by muse, mutect2, varscan2
- FCRLB | c.416A>G p.H139R | Missense Mutation (SNP) | VAF 140/463 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FSIP2 | c.19492A>G p.N6498D | Missense Mutation (SNP) | VAF 152/342 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- IFI16 | c.871C>A p.P291T | Missense Mutation (SNP) | VAF 11/248 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2
- IFI16 | c.872C>A p.P291Q | Missense Mutation (SNP) | VAF 11/247 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- IRX3 | c.590G>T p.S197I | Missense Mutation (SNP) | VAF 316/525 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- ITGA10 | c.2396T>C p.L799P | Missense Mutation (SNP) | VAF 109/384 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- JAK3 | c.1819dup p.A607Gfs*55 | Frame Shift Ins (INS) | VAF 128/414 reads (31%) | called by mutect2, pindel, varscan2
- KCTD8 | c.428T>G p.V143G | Missense Mutation (SNP) | VAF 120/254 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- MAP3K3 | c.412A>G p.R138G | Missense Mutation (SNP) | VAF 69/236 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PAM | c.2826C>A p.S942R (on ENST00000438793 / NM_001319943.1; = p.S943R on NM_000919.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 110/312 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDH17 | c.859C>A p.P287T | Missense Mutation (SNP) | VAF 253/489 reads (52%) | SIFT tolerated (0.2); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- PDE5A | c.1567T>A p.L523M | Missense Mutation (SNP) | VAF 55/137 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PODXL2 | c.1327_1329del p.E443del | In Frame Del (DEL) | VAF 221/432 reads (51%) | called by mutect2, pindel, varscan2
- PRAMEF12 | c.1212C>A p.S404R | Missense Mutation (SNP) | VAF 168/365 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PSMD12 | c.41T>G p.V14G | Missense Mutation (SNP) | VAF 346/546 reads (63%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- PSMD4 | c.292A>G p.K98E | Missense Mutation (SNP) | VAF 111/170 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RALGAPB | c.373A>T p.N125Y | Missense Mutation (SNP) | VAF 54/332 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- RANBP3L | c.1393T>A p.S465T | Missense Mutation (SNP) | VAF 130/183 reads (71%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RTKN | c.46_53delinsCGCCC p.S16_L18delinsRP | In Frame Del (DEL) | VAF 249/669 reads (37%) | called by pindel, varscan2*
- SETD1A | c.3116C>T p.S1039F | Missense Mutation (SNP) | VAF 136/439 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, varscan2
- SLIT3 | c.4544T>G p.L1515* | Nonsense Mutation (SNP) | VAF 156/269 reads (58%) | called by muse, mutect2, varscan2
- SMG7 | c.1476A>T p.L492F | Missense Mutation (SNP) | VAF 182/289 reads (63%) | SIFT tolerated (0.21); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- SOX6 | c.998C>A p.P333Q | Missense Mutation (SNP) | VAF 110/182 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYNE2 | c.16671G>T p.K5557N | Missense Mutation (SNP) | VAF 103/394 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- TMEM132B | c.2893T>C p.S965P | Missense Mutation (SNP) | VAF 105/418 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TRIM45 | c.1595G>T p.G532V | Missense Mutation (SNP) | VAF 82/249 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TTC34 | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 155/342 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- TTN | c.35981C>A p.A11994D (on ENST00000591111; = p.A4570D on NM_003319.4) | Missense Mutation (SNP) | VAF 134/326 reads (41%) | PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- TXLNA | c.436C>T p.R146W | Missense Mutation (SNP) | VAF 83/174 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- YLPM1 | c.2890G>T p.G964W | Missense Mutation (SNP) | VAF 317/420 reads (75%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- ZMYM5 | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 167/336 reads (50%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.017); called by muse, varscan2
- ZNF595 | c.320G>C p.G107A | Missense Mutation (SNP) | VAF 64/132 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- ZZZ3 | c.2051_2053del p.A684del | In Frame Del (DEL) | VAF 60/145 reads (41%) | called by mutect2, pindel, varscan2
- ANK2 | c.657C>T p.D219= | Silent (SNP) | VAF 51/147 reads (35%) | catalogued as rs761137041, COSV52152563, COSV52153636; ClinVar: likely benign; called by muse, mutect2, varscan2
- ARHGEF33 | c.1794G>A p.P598= | Silent (SNP) | VAF 361/786 reads (46%) | called by muse, mutect2, varscan2
- BICRA | c.1320C>T p.P440= | Silent (SNP) | VAF 172/523 reads (33%) | catalogued as rs1459502584; called by muse, mutect2, varscan2
- BICRA | c.4278C>T p.S1426= | Silent (SNP) | VAF 220/683 reads (32%) | catalogued as rs1412801143; called by muse, mutect2, varscan2
- C16orf96 | c.3414C>T p.P1138= | Silent (SNP) | VAF 262/409 reads (64%) | catalogued as rs555858615; called by muse, mutect2, varscan2
- CACNA1S | c.4852C>T p.L1618= | Silent (SNP) | VAF 20/324 reads (6%) | called by muse, mutect2
- CCKBR | c.519C>T p.R173= | Silent (SNP) | VAF 314/483 reads (65%) | catalogued as rs1054148069, COSV100583042; called by muse, mutect2, varscan2
- CELF6 | c.1053C>T p.D351= | Silent (SNP) | VAF 31/596 reads (5%) | catalogued as rs772017152; called by muse, mutect2
- CFAP206 | c.573T>C p.V191= | Silent (SNP) | VAF 67/417 reads (16%) | called by muse, mutect2, varscan2
- CFAP74 | c.2628G>A p.P876= | Silent (SNP) | VAF 91/186 reads (49%) | catalogued as rs777816567; called by muse, mutect2, varscan2
- CLUL1 | c.1083C>G p.L361= | Silent (SNP) | VAF 158/331 reads (48%) | called by muse, mutect2, varscan2
- CNPY4 | c.732C>T p.D244= | Silent (SNP) | VAF 89/297 reads (30%) | catalogued as COSV53541842; called by muse, mutect2, varscan2
- CSMD2 | c.8172C>T p.N2724= | Silent (SNP) | VAF 100/252 reads (40%) | catalogued as rs140959425, COSV53917896; called by muse, mutect2, varscan2
- DCAF12L1 | c.903C>A p.I301= | Silent (SNP) | VAF 480/481 reads (100%) | called by muse, mutect2, varscan2
- DGKI | c.2619G>A p.V873= | Silent (SNP) | VAF 14/201 reads (7%) | called by muse, mutect2
- DLX2 | c.282C>T p.A94= | Silent (SNP) | VAF 342/742 reads (46%) | called by muse, mutect2, varscan2
- DNAH5 | c.9318T>A p.I3106= | Silent (SNP) | VAF 119/333 reads (36%) | called by muse, mutect2, varscan2
- DNAH5 | c.6129G>A p.S2043= | Silent (SNP) | VAF 212/341 reads (62%) | catalogued as rs141459197; called by muse, mutect2, varscan2
- DYNC2I2 | c.492G>A p.V164= | Silent (SNP) | VAF 239/537 reads (45%) | catalogued as COSV100824133; called by muse, mutect2, varscan2
- FER1L6 | c.1932C>T p.I644= | Silent (SNP) | VAF 116/375 reads (31%) | called by muse, mutect2, varscan2
- GOLGA8A | c.282G>A p.A94= (on ENST00000432566; = p.A66= on NM_181077.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 110/246 reads (45%) | catalogued as rs776599161; called by muse, mutect2, varscan2
- IGHE | c.1008G>A p.G336= | Silent (SNP) | VAF 227/886 reads (26%) | called by muse, mutect2, varscan2
- IRX1 | c.1011C>T p.P337= | Silent (SNP) | VAF 464/717 reads (65%) | called by muse, varscan2
- IRX3 | c.591C>T p.S197= | Silent (SNP) | VAF 319/527 reads (61%) | catalogued as rs941103298; called by muse, mutect2, varscan2
- KCNQ4 | c.1974G>A p.P658= | Silent (SNP) | VAF 228/450 reads (51%) | catalogued as COSV61271898; called by muse, mutect2, varscan2
- KDR | c.3495A>G p.Q1165= | Silent (SNP) | VAF 101/199 reads (51%) | called by muse, mutect2, varscan2
- LAMA2 | c.1576A>C p.R526= | Silent (SNP) | VAF 115/308 reads (37%) | called by muse, mutect2, varscan2
- MAP1B | c.2115G>A p.P705= | Silent (SNP) | VAF 91/296 reads (31%) | catalogued as rs766902322, COSV57108392; called by muse, mutect2, varscan2
- NGFR | c.489G>A p.P163= | Silent (SNP) | VAF 178/588 reads (30%) | catalogued as rs751915161, COSV99412629; called by muse, mutect2, varscan2
- NRROS | c.708C>T p.N236= | Silent (SNP) | VAF 298/620 reads (48%) | catalogued as rs139757136; called by muse, mutect2, varscan2
- OR2V2 | c.840G>A p.T280= | Silent (SNP) | VAF 146/372 reads (39%) | catalogued as COSV100080104, COSV60315109; called by muse, mutect2, varscan2
- OR8J2 | c.343C>T p.L115= | Silent (SNP) | VAF 197/282 reads (70%) | catalogued as rs775832934; called by muse, mutect2, varscan2
- PCNX1 | c.4701C>T p.S1567= | Silent (SNP) | VAF 91/359 reads (25%) | called by muse, mutect2, varscan2
- PRPS1L1 | c.6G>A p.P2= | Silent (SNP) | VAF 152/258 reads (59%) | catalogued as rs1169327133; called by muse, mutect2, varscan2
- ROS1 | c.2172C>T p.G724= | Silent (SNP) | VAF 285/483 reads (59%) | catalogued as rs528202634, COSV63853561; called by muse, mutect2, varscan2
- RTN4RL1 | c.963C>T p.T321= | Silent (SNP) | VAF 212/214 reads (99%) | catalogued as rs1395874156; called by muse, varscan2
- RXFP3 | c.1302G>T p.P434= | Silent (SNP) | VAF 190/613 reads (31%) | called by muse, mutect2, varscan2
- SHANK1 | c.3354C>T p.G1118= | Silent (SNP) | VAF 231/708 reads (33%) | called by muse, mutect2, varscan2
- SLC2A14 | c.741G>A p.T247= | Silent (SNP) | VAF 107/208 reads (51%) | catalogued as rs756918734, COSV61585491; called by muse, mutect2, varscan2
- SLCO6A1 | c.291C>T p.T97= | Silent (SNP) | VAF 75/291 reads (26%) | called by muse, mutect2, varscan2
- SOBP | c.2553C>T p.S851= | Silent (SNP) | VAF 310/562 reads (55%) | called by muse, mutect2, varscan2
- TENM3 | c.3798G>A p.P1266= | Silent (SNP) | VAF 131/222 reads (59%) | catalogued as rs537485392, COSV101305120, COSV69316053; called by muse, mutect2, varscan2
- TRDN | c.375C>T p.D125= | Silent (SNP) | VAF 122/362 reads (34%) | catalogued as rs377440434; ClinVar: likely benign / conflicting interpretations of pathogenicity; called by muse, mutect2
- TSPYL5 | c.786A>G p.L262= | Silent (SNP) | VAF 21/538 reads (4%) | called by muse, mutect2
- TTN | c.807G>A p.P269= | Silent (SNP) | VAF 187/391 reads (48%) | catalogued as rs779966449; called by muse, mutect2, varscan2
- TWIST2 | c.243G>A p.S81= | Silent (SNP) | VAF 334/645 reads (52%) | called by muse, mutect2, varscan2
- TXNIP | c.1173G>A p.Q391= | Silent (SNP) | VAF 112/188 reads (60%) | called by muse, mutect2, varscan2
- XPOT | c.2172A>G p.P724= | Silent (SNP) | VAF 206/455 reads (45%) | called by muse, mutect2, varscan2
- ZP4 | c.700C>T p.L234= | Silent (SNP) | VAF 81/231 reads (35%) | catalogued as COSV63911335; called by muse, mutect2, varscan2
- AC092070.2 | n.1148T>C | RNA (SNP) | VAF 96/301 reads (32%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73821976 A>G | 5'Flank (SNP) | VAF 231/231 reads (100%) | called by muse, mutect2, varscan2
- PDE4A | chr19:10417707 C>A | 5'Flank (SNP) | VAF 160/503 reads (32%) | called by muse, mutect2, varscan2
